CCDI case PBCAZK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/40511f59-6266-4c83-9d3a-859d0c0f179f

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 3.4 years (1,226 days).

Biospecimens (2 samples)
- Sample 0DMWTT: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DMWU1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
